Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96C, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96C-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 12.0 x 8.0 x 7.0 cm

Infiltration of capsule

Diagnosis:

Type A/B Thymoma

pT1, pN0 (0/2), pMx

Masaoka: I

ICD O-3

Thymoma, type AB,
malignant 858213
Site Thymus C37.9
JTD 4/7/14

Prior ovarian cancer -

DQ - unknown systemic therapy
w/ 1/10/14

Prior Malignancy History	ovary ✓	✓

Source: NCI Genomic Data Commons file 5b25618d-efbe-4d0a-b43a-d52b313d9d10 (TCGA-ZB-A96C.B91A8D4C-B663-4232-96CF-A4609DC65316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).